Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PE, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PE-01A (Primary Tumor).

[page 1 of 2]
CCF
ICD O-3
Adenocarcinoma, tubular 8211/3
Adenocarcinoma w/ mixed cell types 8255/3
Site: Gastric cardia C16.0
JW 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

1 - "Gastrectomy" 2 - "Greater omentum" and 4 - "Standardization":
Adenocarcinoma characterized thus:

Location: cardia.

Borman Classification: Type III

Histological pattern observed:

- Tubular - Per TSS, 100% tubular. See dx discrepancy form. BCR
- Solid
- Villous

Histologic grade: III - poorly differentiated

Lauren's classification: intestinal pattern

Ulceration: present

Type of tumor invasion: spiculate

Inflammatory reaction: moderate

Tumor implantation in peri-visceral adipose tissue: not detected

Proximal and distal margins: absence of neoplastic involvement.

Neural infiltration and blood vascular invasion: not detected

Lymphatic vascular invasion: present

Greater omentum: absence of neoplastic involvement

Lymph nodes: Involved, without capsular transposition

Lymph node conglomerates: Undetected

List of involved/dissected lymph nodes: 12/36

Discrimination lymph according to standardization, ratio involved/ dissected):

F - Chain 1 - right paracardic: 1/4

G - Chain 2 - left paracardic: 0/3

H - Chain 3 - along the lesser curvature: 7/10

I - Chain 4sa - along the short gastric vessels: 0/0

J - Chain 4sb - along the left gastroepiploic vessels: 0/0

K - Chain 4d - along the right gastroepiploic vessels: 0/1

L - Chain 5 - suprapylorics: 0/0

M - Chain 6 - infrapylorics: 0/8

N - Chain 7 - along the left gastric artery: 3/3

O - Chain 8a - along the anterior hepatic artery (antero superior group): 0/2

Q - Chain 9 - around the celiac trunk: 1/4

S - Chain 11p - along the proximal splenic artery: 0/1

3 - "Esophageal margin": Absence of neoplastic involvement.

ADDENDUM - Neoplasia affects from the sub-mucosa until the serosa and adjacent mesenteric fat.
The peritoneal lining is integrate.

Pathological staging: pT3 pN3a

Per TSS, dx discrepancy form states
TCGA tumor to be
adenocarcinoma, tubular. BCR

Diagnosis Discrepancy Per TSS, dx discrepancy form states	☒	☒
HPV A Discrepancy	☒	☒

TSS pathologist confirms 100% tubular

[page 2 of 2]
V4 00

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Tubular, Solid, Villous Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Tubular (100%)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on top slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	<hr/>	Provide the name of the pathologist who reviewed this case for TCGA.

Date _____

Date _____

HPV A Discrepancy		☒
History: Malignancy History		☒

Source: NCI Genomic Data Commons file cfad9d37-2fdf-46cb-8146-180b37215a5e (TCGA-VQ-A8PE.B20722B4-6F27-43F9-BA08-A4FAA31A414D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).